CPTAC case C3N-00466 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/75a61754-30e9-4ad0-9c20-5761b9bbc4ab

Demographics
Sex at birth: male; Race: white; Year of birth: 1971; Vital status: Alive; Country of birth: Ukraine.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Age at diagnosis: 45.8 years (16,720 days); Year of diagnosis: 2016; Days to last known disease status: 8 days; Days to last follow up: 8 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 8.

Other clinical attributes
- Weight: 80 kg; Height: 186 cm; BMI: 23.12.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 29; Cigarettes per day: 20; Tobacco smoking onset year: 1987; Tobacco smoking quit year: 2016; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 29.

Biospecimens (16 samples)
- Samples C3N-00466-33, C3N-00466-60, C3N-00466-61 (3 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Samples C3N-00466-35, C3N-00466-36, C3N-00466-57, C3N-00466-58, C3N-00466-59, C3N-00466-63, C3N-00466-64 (7 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-00466-50: Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen.
- Samples C3N-00466-51, C3N-00466-52 (2 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3N-00466-54, C3N-00466-55, C3N-00466-56 (3 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 8 days; Time between excision and freezing: 390 minutes; Method of sample procurement: Blood Draw; Diagnosis pathologically confirmed: Yes.
